Somatic mutation profile of tumor specimen TCGA-CQ-7069-01A (aliquot TCGA-CQ-7069-01A-11D-2394-08) from TCGA case TCGA-CQ-7069, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 77.0 years (28,138 days).
Specimen TCGA-CQ-7069-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a19da6d-0763-4316-925f-b37d81cb6114.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-7069-10A (Blood Derived Normal), aliquot TCGA-CQ-7069-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce778bfb-63a6-41a6-a121-bb2f8fd8e8ab

The open-access MAF lists 97 somatic variants for this specimen: 75 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 19, Nonsense Mutation 7, Frame Shift Del 2, Intron 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV99908172; called by muse, mutect2, varscan2
- ABCA13 | c.11627C>T p.T3876I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101447060; called by muse, mutect2, varscan2
- ABCA5 | c.3217G>C p.D1073H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101201202; called by muse, mutect2
- ACBD3 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1258625946, COSV100831080; called by muse, mutect2
- ADCK5 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV100450319; called by muse, mutect2, varscan2
- ADGRG4 | c.3155C>G p.S1052* | Nonsense Mutation (SNP) | VAF 83/340 reads (24%) | catalogued as COSV99796079; called by muse, mutect2, varscan2
- ADGRG4 | c.6632C>T p.P2211L | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99796081; called by muse, mutect2, varscan2
- AFF1 | c.1244C>G p.S415C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100320216, COSV100320866; called by muse, mutect2, varscan2
- ALDH5A1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs751888532, CM1314748, COSV100708854; called by muse, mutect2, varscan2
- ALG12 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 24/114 reads (21%) | PolyPhen probably damaging (0.997); catalogued as COSV100427163; called by muse, mutect2, varscan2
- AP1G1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100250701; called by muse, mutect2, varscan2
- AQR | c.2219C>G p.P740R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.242); catalogued as COSV99333360, COSV99334319; called by muse, mutect2, varscan2
- AQR | c.66C>G p.F22L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV99333927, COSV99334321; called by muse, mutect2, varscan2
- ATR | c.2959C>A p.L987I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.283); catalogued as COSV100638391; called by muse, mutect2, varscan2
- BLM | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV100757264; called by muse, varscan2
- BRINP3 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs773859506, COSV66531362; called by muse, mutect2, varscan2
- C14orf39 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); catalogued as COSV100407882; called by muse, mutect2, varscan2
- CABIN1 | c.2528C>G p.S843C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV54082923; called by muse, mutect2, varscan2
- CARMIL1 | c.1352A>T p.N451I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100278380; called by muse, mutect2, varscan2
- CCDC191 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs202109497, COSV99878502; called by muse, mutect2, varscan2
- CDC42BPA | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506138; called by muse, mutect2, varscan2
- CEP152 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | catalogued as COSV100358992; called by muse, mutect2, varscan2
- CHST2 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042624925, COSV100536034; called by muse, mutect2, varscan2
- CHUK | c.1569+1G>A p.X523_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | catalogued as COSV64918273; called by muse, mutect2, varscan2
- CLIC5 | c.855C>G p.I285M (on ENST00000185206 / NM_001370649.1; = p.I126M on NM_016929.5) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV99484930; called by muse, mutect2, varscan2
- COL12A1 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100486255; called by muse, mutect2, varscan2
- DNAH9 | c.4791G>C p.K1597N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52363642; called by muse, mutect2, varscan2
- DNAJC4 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs746346153, COSV99655952; called by muse, mutect2, varscan2
- ELK1 | c.264C>A p.Y88* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99902234; called by muse, mutect2, varscan2
- EMC2 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99624352; called by muse, mutect2, varscan2
- EPHA2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777774171, COSV100626216; called by muse, mutect2
- FBXL13 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1284029625, COSV50864337, COSV50868760; called by muse, mutect2, varscan2
- FBXL13 | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as COSV100501899; called by muse, mutect2, varscan2
- FOXF2 | c.1169C>G p.S390* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99453371; called by muse, mutect2, varscan2
- IL12RB2 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99255415; called by muse, mutect2, varscan2
- JMJD1C | c.5167G>A p.E1723K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100550711; called by muse, mutect2, varscan2
- KIF14 | c.3300C>G p.I1100M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100950726; called by muse, varscan2
- KLHL2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99900111; called by muse, mutect2, varscan2
- LYSMD4 | c.532G>C p.E178Q (on ENST00000409796 / NM_001284417.2; = p.E179Q on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.509); catalogued as COSV100230653; called by muse, mutect2, varscan2
- MAGEB18 | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.808); catalogued as COSV100305549; called by muse, mutect2, varscan2
- MAML1 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV52988505, COSV99483219; called by muse, mutect2, varscan2
- MBD6 | c.881C>G p.T294S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV100851731; called by muse, mutect2, varscan2
- MRPS18A | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100928750; called by muse, mutect2, varscan2
- NFAT5 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100590994; called by muse, mutect2
- NLRX1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1272387360, COSV99424569; called by muse, mutect2, varscan2
- NOTCH3 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV99658082; called by muse, mutect2, varscan2
- NXPH1 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339647, COSV101339751; called by muse, mutect2, varscan2
- OR5D14 | c.771C>G p.I257M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1403015647, COSV100162368, COSV100162503, COSV100162592; called by muse, mutect2, varscan2
- PAX7 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs761460050, COSV64751693; called by muse, mutect2
- PDSS2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100941830; called by muse, mutect2, varscan2
- PLEC | c.4051G>A p.E1351K (on ENST00000322810 / NM_201380.4; = p.E1241K on NM_000445.5) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs922709138, COSV100516385; called by muse, mutect2, varscan2
- POLN | c.1564C>G p.L522V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101242595; called by muse, mutect2, varscan2
- RB1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM961231, COSV57298872, COSV57315903; called by muse, mutect2, varscan2
- ROS1 | c.3919C>G p.H1307D | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV100877425; called by muse, mutect2, varscan2
- RPL10A | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100003459; called by muse, mutect2, varscan2
- RYR1 | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100616340, COSV99052041; called by muse, mutect2, varscan2
- SGK1 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV99398778; called by muse, mutect2, varscan2
- SH2D3C | c.2507G>A p.R836H (on ENST00000314830 / NM_170600.3; = p.R679H on NM_005489.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200069549, COSV100137187; called by muse, varscan2
- SMC6 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61173504; called by muse, mutect2
- STK33 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as rs768634610, COSV100174277, COSV59399843; called by muse, mutect2, varscan2
- TRHDE | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs763824446, COSV99671663; called by muse, mutect2, varscan2
- TRIM6 | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as COSV99546581; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV99691888; called by muse, mutect2
- USH2A | c.12622G>A p.D4208N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs529589990, COSV56412301; called by muse, mutect2, varscan2
- VPS52 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV101460449; called by muse, mutect2, varscan2
- VWA7 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100991907; called by muse, mutect2, varscan2
- WAS | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.594); catalogued as CM961456, COSV100939512; called by muse, mutect2, varscan2
- WDR33 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs770304067, COSV100460372; called by muse, mutect2, varscan2
- YIPF3 | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as rs1397418892, COSV100397011; called by muse, mutect2, varscan2
- ZBED9 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.834); catalogued as rs778226085, COSV101509331, COSV71729635; called by muse, mutect2, varscan2
- ZNF142 | c.3739G>C p.E1247Q (on ENST00000411696 / NM_001379660.1; = p.E1047Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV101376965; called by muse, mutect2, varscan2
- ZNF623 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV101513580; called by muse, varscan2
- ZNF623 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101513581; called by muse, mutect2, varscan2
- FOSL2 | c.604_617del p.P202Afs*52 | Frame Shift Del (DEL) | VAF 42/101 reads (42%) | called by mutect2, pindel, varscan2
- FRMD8 | c.153del p.L52Sfs*37 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | called by mutect2, pindel
- ADAM23 | c.474C>T p.F158= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs141683172; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCAP31 | c.78C>T p.F26= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99497783; called by muse, mutect2, varscan2
- C6orf118 | c.639C>T p.D213= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100024776; called by muse, mutect2, varscan2
- DUSP23 | c.447G>A p.T149= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV63660666; called by muse, mutect2, varscan2
- FBXW10 | c.894G>C p.L298= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV100111581; called by muse, mutect2, varscan2
- FHL2 | c.558C>T p.F186= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs892899914, COSV100363069; called by muse, mutect2
- FSIP1 | c.1167G>A p.L389= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV100618193; called by muse, mutect2, varscan2
- GPI | c.90C>T p.F30= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs368450858, COSV62894623; called by muse, mutect2
- MAN1C1 | c.1440G>A p.Q480= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV99848696; called by muse, mutect2, varscan2
- N4BP2L1 | c.360C>T p.N120= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100583087; called by muse, mutect2, varscan2
- OR5B17 | c.649C>T p.L217= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs768891222, COSV100641931; called by muse, mutect2, varscan2
- PCDHA13 | c.1443C>T p.D481= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs1554179442, COSV56500898; called by muse, mutect2, varscan2
- PLXND1 | c.3120C>A p.A1040= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1228786107, COSV100140109; called by muse, mutect2, varscan2
- PRDM8 | c.831C>T p.C277= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs368682315; called by muse, mutect2, varscan2
- SRL | c.1083C>T p.F361= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV101281358; called by muse, mutect2, varscan2
- THSD1 | c.1071G>T p.G357= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as COSV99318976; called by muse, mutect2, varscan2
- TTN | c.62481T>C p.C20827= (on ENST00000591111; = p.C13403= on NM_003319.4) | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100621147; called by muse, mutect2, varscan2
- ZCCHC14 | c.1971T>C p.C657= (on ENST00000268616; = p.C794= on NM_015144.3) | Silent (SNP) | VAF 34/196 reads (17%) | catalogued as COSV99234246; called by muse, mutect2, varscan2
- ZNF536 | c.2631T>G p.S877= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV100835507; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1438C>G | Intron (SNP) | VAF 38/185 reads (21%) | catalogued as rs910415829, COSV100801802; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846748 G>A | 5'Flank (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- SNX5 | c.51+5460G>T | Intron (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100899035; called by muse, mutect2, varscan2
